Somatic mutation profile of tumor specimen 0DG38C from CCDI case PBBPXG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,951 days).
Specimen 0DG38C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 639c6426-5bc1-4111-88b6-da6e9b6e4407.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG387 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed5c3ae-830a-46c9-af91-c6d579803354

The open-access MAF lists 22 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 5, 3'UTR 3, Silent 3, RNA 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 200/241 reads (83%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by mutect2, varscan2
- BNC2 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 212/408 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as rs535983413, COSV66156428; called by muse, mutect2, varscan2
- DMAP1 | c.-45-5_-45-3del | Splice Region (DEL) | VAF 74/130 reads (57%) | catalogued as rs1267559018; called by pindel, varscan2
- GNA13 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428893998; called by muse, mutect2
- OR9K2 | c.979T>A p.F327I (on ENST00000305377; = p.F305I on NM_001005243.1) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59533770; called by muse, varscan2
- FREM3 | c.3817T>A p.S1273T | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); called by muse, mutect2
- SLFN5 | c.1885C>A p.P629T | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STXBP3 | c.335_337+1del | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by pindel, varscan2
- GCNT1 | c.1110G>A p.P370= | Silent (SNP) | VAF 35/493 reads (7%) | catalogued as rs771375099, COSV100946498, COSV65057782; called by muse, mutect2
- KCNH4 | c.1587C>T p.N529= | Silent (SNP) | VAF 73/295 reads (25%) | catalogued as rs765016708, COSV99237337; called by muse, mutect2, varscan2
- MVK | c.1020C>T p.G340= | Silent (SNP) | VAF 62/345 reads (18%) | catalogued as rs537579532; called by muse, mutect2, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 6/41 reads (15%) | called by muse, varscan2
- CHD8 | c.5391-66A>G | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- EDA | c.396+53529C>T | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as rs1311947450, COSV58877982; called by mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 4/36 reads (11%) | catalogued as rs768118261; called by mutect2, varscan2
- NAPRT | c.1554+12G>A | Intron (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- SAG | c.807-84del | Intron (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- ST8SIA4 | c.*1833G>A | 3'UTR (SNP) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- VAV1 | c.*47C>T | 3'UTR (SNP) | VAF 18/57 reads (32%) | catalogued as rs779845211; called by muse, mutect2, varscan2
- VPS26C | c.812-59C>T | Intron (SNP) | VAF 18/75 reads (24%) | catalogued as rs754378069; called by muse, mutect2, varscan2
